Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17H-01A (Primary Tumor).

[page 1 of 4]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium (54.1) *ju*

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (6.6 x 6.2 x 1.6 cm), circumferentially involving the endometrial cavity. The tumor invades 0.8 cm into the myometrium (total wall thickness, 1.4 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are unremarkable. [AJCCpT1cN0M0].

B. C. D. E. Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (3 external iliac, 4 internal iliac, 3 common iliac, and 2 obturator) are negative for tumor.

F. G. H. I. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (6 external iliac, 3 internal iliac, 3 common iliac, and 4 obturator) are negative for tumor.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

**GROSS DESCRIPTION:**

A. Received fresh labeled "uterus, right and left ovaries and fallopian tubes" is a 105.0 gram uterus with attached bilateral

[page 2 of 4]
tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth. There is a 6.6 x 6.2 x 1.6 cm mass from the fundus to lower uterine segment of the endometrial cavity with 1.4 cm myometrial thickness, 0.8 cm invasion into the myometrium. There is a 2.7 x 1.6 x 0.8 cm right ovary with a smooth outer surface and a solid cut surface with a 6.9 x 0.4 cm right fallopian tube. There is a 2.7 x 1.4 x 0.7 cm left ovary with a smooth outer surface and a solid cut surface with a 8.1 x 0.4 cm left fallopian tube. Representative sections are submitted.

B. Received fresh labeled "right pelvic internal iliac" is a 2.5 x 2.0 x 0.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "right pelvic external iliac" is a 4.5 x 4.0 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

D. Received fresh labeled "right common iliac" is a 4.0 x 3.5 x 0.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right obturator" is a 5.5 x 4.5 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "left pelvic internal iliac" is a 1.8 x 1.2 x 0.9 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 3 of 4]
G. Received fresh labeled "left pelvic external iliac" is a 4.4 x

3.6 x 1.9 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

H. Received fresh labeled "left common iliac" is a 3.2 x 1.8 x 1.2

cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

I. Received fresh labeled "left obturator" is a 6.2 x 2.8 x 1.4 cm

aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, right and left tubes and ovaries

- 1 Posterior fundus
- 2 Ant myometrium
- 3 Lower uterine segment
- 4 Cervix 6:00
- 5 Ant endomyometrium
- 6 Post endomyometrium
- 7 Right fallopian tube
- 8 Right ovary
- 9 Left fallopian tube
- 10 Left ovary

Part B: Right Pelvic Lymph Nodes internal

- 1 Rt internal LNs-5(B1)

Part C: Right Pelvic Lymph Nodes external

- 1 Rt external LN(1of2) (C1)
- 2 Rt external LN(2of2) (C1)
- 3 Rt external LN(1of2) (C2)
- 4 Rt external LN(2of2) (C2)
- 5 Rt external LN-1(C3)

Part D: Right Pelvic Lymph Nodes common

- 1 Rt common lns 3 (D1)

Part E: Right Pelvic Lymph Nodes obturator

- 1 Rt obturator lns 2 (E1)

[page 4 of 4]
- 2 Rt obturator lns 1of8 (E2)
- 3 Rt obturator lns 2of8 (E2)
- 4 Rt obturator lns 3of 8 (E2)
- 5 Rt obturator lns 4of8 (E2)
- 6 Rt obturator lns 5of8 (E2)
- 7 Rt obturator lns 6of8 (E2)
- 8 Rt obturator lns 7of8 (E2)
- 9 Rt obturator lns 8of8 (E2)

Part F: Left Pelvic Lymph Nodes internal
1 Lt internal LN-1(F1)

Part G: Left Pelvic Lymph Nodes external
1 Lt external LNS-4(G1)
2 Lt external LN(1of2)(G2)
3 Lt external LN(2of2)(G2)
4 Lt external LN(1of2)(G3)
5 Lt external LN(2of2)(G3)

Part H: Left Pelvic Lymph Nodes common
1 Lt common LNS 2 (H1)
2 Lt common LN 1 (H2)

Part I: Left Pelvic Lymph Nodes obturator
1 Lt obturator LNS 3 (I1)
2 Lt obturator LNS 3 (I2)
3 Lt obturator LN (1of4)(I3)
4 Lt obturator LN (2of4)(I3)
5 Lt obturator LN 3of4 (I3)
6 Lt obturator LN 4of4 (I3)

Source: NCI Genomic Data Commons file 49612cf6-0f4e-4014-9ec4-090b6f77107d (TCGA-D1-A17H.E2EBC803-BE77-4936-9B6A-9E6E7E6B8FA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).